Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A2H4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A2H4-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

adenocarcinoma, serous, NOS 8441/3

Site endometrium C54.1

for 6/19/11

SURGICAL PATHOLOGY REPORT

PATIENT:

MR #: 1

ACCT #: 1

DOB:

AGE:

SEX: F

PATHOLOGY NO:

LOCATION: UNIT:

RM:

DOCUMENT TYPE:

OFFICE CHART/IDX #:

REQUESTING PHYSICIAN:

DATE RECEIVED:

SPECIMEN(S) SUBMITTED:

A. Left External Iliac

B. Left Common Iliac

C. Left Obturator Node

D. Left Aortic Node

E. Left Common Node

F. Uterus, Tubes, And Ovaries

SPECIAL ANATOMIC STUDIES REQUESTED:

PRE/POST OP DIAGNOSIS: Pelvic mass, uterine bleeding/Endometrial cancer

CLINICAL INFORMATION:

OPERATION PERFORMED: Total abd. hyst.

DATE OF OPERATION:

CULTURES TAKEN?

Portion to Cytology

DATE DICTATED:

DATE TRANSCRIBED:

GROSS DESCRIPTION: The information submitted on the requisition form and on the specimen container labels have been reviewed and verified to match. The specimen is received in six parts.

Part A received fresh labeled , and "left external iliac" consists of a portion of fibroadipose tissue measuring 2 x 1 x 0.3 cm. The specimen is entirely submitted in one cassette labeled A.

Part B received fresh labeled , and "left common iliac" consists of a portion of tan-yellow fibroadipose tissue measuring 1.2 x 0.4 x 0.2 cm. The specimen is entirely submitted in one cassette labeled B.

Part C received fresh labeled , and "left obturator node" consists of a portion of tan-yellow to tan-pink fibroadipose tissue measuring 1 x 0.8 x 0.3 cm. The specimen is entirely submitted in one cassette labeled C.

Part D received fresh labeled , and "left aortic node" consists of a fragment of tan-pink soft tissue measuring 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted in one cassette labeled D.

Part E received fresh labeled , and "left common node" consists of a portion of tan-brown soft tissue measuring 1.2 x 0.8 x 0.3 cm. The specimen is entirely submitted in one cassette labeled E.

SURGICAL PATHOLOGY REPORT

Page 1 of 4

[page 2 of 3]
Department of Pathology

PATIENT: ...
PATHOLOGY #:

Part F received fresh labeled 1, and "uterus, tubes, and ovaries" consists of a uterus with attached cervix and left and right fallopian tube.

The uterus measures 8 cm superior to inferior, 7 cm laterally, and 2.5 cm anterior to posterior and weighs 160 grams. The left anterior serosa has a 3 x 2.5 x 0.3 cm irregular tan-yellow irregular ulcerated mass attached to the left round ligament and a 0.5 x 0.4 x 0.3 cm nodule 0.8 cm inferior to mass.

The uterus is inked as follows: anterior - green, posterior - yellow, and the cervix is amputated and the uterus is bisected into anterior and posterior halves revealing an irregular papillary mass primarily within the anterior endometrial cavity measuring 2 x 2 cm. After inking, the cut sections of the mass on the serosal surface are tan-yellow. Cut sections of the smaller tan nodule are well circumscribed and tan-white. The myometrium measures 1.3 cm in maximal thickness and the tumor is seen to invade to a thickness of 1.3 cm in the anterior endomyometrium. The myometrium in the posterior portion measures 0.5 cm and the tumor is seen to invade to a thickness of 0.3 cm. Cut sections of the remaining myometrium are tan-pink and smooth. No other nodules are seen.

The cervical margin is irregular, disrupted and friable with multiple papillary areas. This area measures 5.5 x 5 cm. The amputated cervix is opened at the 12:00 position and sectioned clockwise and entirely submitted.

The left ovary measures 3 x 2 x 1 cm and weighs 3 grams. Cut sections of the left ovary are tan-pink with a central tan-yellow area measuring 1 x 0.8 x 0.2 cm. The left fallopian tube is irregular and thickened and consists mainly of distal fimbriated end measuring 3.5 x 0.3 cm.

The right ovary measures 2 x 2 x 0.3 cm and weighs 2 grams. The right fallopian tube measures 4 x 0.5 cm. Cut sections of the right ovary are tan-pink.

SUMMARY OF SECTIONS: F1 and F2 - tumor with anterior endomyometrium; F3 and F4 - tumor with posterior endomyometrium; F5 through F7 - irregular area on serosal surface; F8 - nodule on serosal surface; F9 - right ovary and fallopian tube; F10 - left ovary and fallopian tube; F11 - right side of cervix; F12 - left side of cervix. The cervix is entirely submitted as follows. F13 and F14 - 1:00; F15 and F16 - 2:00; F17 - 3:00; F18 - 4:00; F19 - 5:00; F20 - 6:00; F21 and F22 - 7:00; F23 - 8:00; F24 and F25 - 10:00; F26 and F27 - 9:00; F28 - 11:00; F29 - 12:00. (

MICROSCOPIC: A poorly differentiated papillary serous adenocarcinoma of the endometrium is seen infiltrating throughout the myometrium and out onto the serosal surface. There is extensive vascular invasion. The neoplasm is also seen to involve cervix including endocervical glands and cervical stromal invasion. The left ovary and fallopian tube are also infiltrated by tumor as well as the left and right sides of the cervix. The tumor shows extensive necrosis, poorly formed glands and extensive single cell infiltration. Lymphovascular space involvement is seen throughout the sections.

[page 3 of 3]
Department of Pathology

PATIENT:

PATHOLOGY #:

DIAGNOSIS:

- A. Left external iliac:
1. Fibroadipose tissue.
2. No lymph node seen.
3. No malignancy seen.
- B. Left common iliac:
1. Fibroadipose tissue.
2. No lymph node seen.
3. No malignancy seen.
- C. Left obturator node:
1. Fibroadipose tissue.
2. No lymph node seen.
3. No malignancy seen.
- D. Left aortic node:
1. Fibroadipose tissue.
2. No lymph node seen.
3. No malignancy seen.
- E. Left common node:
1. Granulation tissue with focal hemorrhage.
2. No malignancy seen.
- F. Uterus, tubes and ovaries, total abdominal hysterectomy:
1. Tumor type: Papillary serous adenocarcinoma.
2. FIGO grade:
- a. Architectural grade 3.
- b. Nuclear grade: 3.
3. Size: At least 5 cm in maximum dimension.
4. Depth of invasion:
- a. Tumor invades through the entire thickness of the myometrium (1.3 cm).
- b. Thickness of myometrium: 1.3 cm.
- c. Serosa is involved by neoplasm.

Source: NCI Genomic Data Commons file c87c7ef5-61c1-46e6-8d3a-5b11a1ad2b5f (TCGA-AX-A2H4.5230A27B-4AA6-4ED9-90BB-98C6671E0B2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).